Gene-level copy-number profile of tumor specimen TCGA-PL-A8LX-01A from TCGA case TCGA-PL-A8LX, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 35.2 years (12,840 days).
Specimen TCGA-PL-A8LX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.e28bac01-5bd3-4b66-83f7-2c778be9a0d5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-PL-A8LX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6a83b19d-999d-4f5c-909f-47b9006009f2

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 124; copy number 2: 5,296; copy number 3: 19,536; copy number 4: 30,667; copy number 5: 1,056; copy number 6: 2,771; copy number 7: 150; copy number 8: 184; copy number 9: 17; copy number 10: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-PL-A8LX-01A-11D-A41E-01): tumor purity 0.57, ploidy 3.58, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 32 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:72,047,873–72,251,288, 17 genes, copy number 9: RNU6-72P, MIR3165, AP000812.4, LRTOMT, LAMTOR1, AP000812.3, ANAPC15, FOLR3, RPEP6, FOLR1P1, AP000812.1, AP000812.2, FOLR1, FOLR2, INPPL1, PHOX2A, AP000593.2.
- chr15:26,971,181–28,099,315, 15 genes, copy number 10 (within-gene range 6–10): GABRG3, GABRG3-AS1, AC136896.1, RNA5SP391, SERPINE4P, AC144833.1, AC104002.1, AC104002.2, AC104002.3, AC021979.1, AC021979.3, AC021979.2, OCA2, AC090696.1, RPL5P32.

Autosomal genes at a single copy (total copy number 1): 124. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
